Somatic mutation profile of tumor specimen TARGET-20-PASAFH-09A (aliquot TARGET-20-PASAFH-09A-01D) from TARGET case TARGET-20-PASAFH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.2 years (5,566 days).
Specimen TARGET-20-PASAFH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94729eb6-e3bd-451e-897f-a5105a05ff2b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASAFH-14A (Bone Marrow Normal), aliquot TARGET-20-PASAFH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8bcbc3d-9f91-4673-9422-8c177c77631f

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Splice Site 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>A p.N822K | Missense Mutation (SNP) | VAF 69/162 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.4715+1_4715+21delinsAA p.X1572_splice | Splice Site (DEL) | VAF 46/116 reads (40%) | hotspot (GDC flag); called by pindel, varscan2*
- ASXL1 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 57/132 reads (43%) | catalogued as rs764325672; called by muse, mutect2, varscan2
- NRXN1 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866241948, COSV100455890; called by muse, mutect2, varscan2
- ELF4 | c.761A>G p.Q254R | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- PHF6 | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PTBP1 | c.*845C>T | 3'UTR (SNP) | VAF 82/159 reads (52%) | called by muse, mutect2, varscan2
